Surgical pathology report (de-identified scan), TCGA case TCGA-MH-A562, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MH-A562-01A (Primary Tumor).

[page 1 of 2]
---- SURGICAL PATHOLOGY ----

MEDICAL RECORD |

| SURGICAL PATHOLOGY

PATHOLOGY REPORT

LEFT KIDNEY TUMOR

100-0-3

BRIEF CLINICAL HISTORY:

carcinoma, papillary renal cell 8260/3

PREOPERATIVE DIAGNOSIS:

Renal Mass

Site: Kidney, NOS c64.9

hw 11/25/12

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

Renal Mass

PATHOLOGY REPORT

GROSS DESCRIPTION:

The specimen is received fresh and consists of an 8.2 gm, 3.0 x 2.8 x 2.3 cm, partial nephrectomy specimen displaying a tan-brown, granular renal resection margin. The renal capsule is tan-white and smooth. There is minimal attached perinephric fat. The specimen is inked blue along the renal resection margin and black along the renal capsule resection margin. The specimen is serially sectioned to reveal a 1.8 x 1.8 x 1.8 cm, tan-white to yellow, granular, well-circumscribed mass that is 0.2 cm from the renal resection margin and grossly abuts the capsular margin. The specimen is submitted in its entirety sequentially in cassettes 1-5.

Please note that a representative portion of tumor is taken for tissue bank.

MICROSCOPIC EXAM

DIAGNOSIS:

Kidney, left, partial nephrectomy:
- PAPILLARY RENAL CELL CARCINOMA

PROCEDURE: Partial nephrectomy

SPECIMEN LATERALITY: Left

TUMOR SIZE:

Greatest dimension: 1.8 cm
Additional dimensions: 1.8 x 0.8 cm

TUMOR FOCALITY: Unifocal

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGICAL TYPE: Papillary renal cell carcinoma

SARCOMATOID FEATURES: Not identified

TUMOR NECROSIS: Not identified

[page 2 of 2]
HISTOLOGICAL GRADE: Fuhrman Nuclear Grade 3

NOTE: The tumor is predominantly Type 1; however, there are areas of Type 2 histology which show nuclear grade 3 features.

MICROSCOPIC TUMOR EXTENSION: Tumor limited to kidney

MARGINS: Margins uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION: Not identified.

PATHOLOGICAL STAGING:

Primary Tumor: pT1a

Regional Lymph nodes: pNX

Distant Metastasis: Not applicable

PATHOLOGICAL FINDINGS IN NONNEOPLASTIC KIDNEY: Insufficient tissue

NOTE: concurs with the diagnosis of malignancy in this case. The Urology Department informed at

Staff pathologist

(End of report)

Staging Discrepancy		✓
Reviewer Initials	BNE	Date Received: 11/21/2012

Source: NCI Genomic Data Commons file 4d5fbaa4-d96d-48d7-bed8-803ee051e2bf (TCGA-MH-A562.1A100A60-EDE2-4844-A17A-19B9520D05F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).